Surgical pathology report (de-identified scan), TCGA case TCGA-CC-A9FV, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site ILSBio, specimen TCGA-CC-A9FV-01A (Primary Tumor).

[page 1 of 5]
Clinical Case Report **(For Collection of Cancerous Tissue)**

ICDO 3

Carcinoma, hepatocellular
NOS 8170/3

Date given C22.0
QD 4/7/14

Informed Consent

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Name of Physician or Study Coordinator

Signature

Date

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status	Race	Temperature
Gender	Weight	☐ Single ☒ Married ☐ Divorced ☐ Widow	Vietnamese	
☒ Male ☐ Female			Blood Pressure	Heart Rate

HISTORY OF PRESENT ILLNESS
Chief Complaints: Abdominal pain, not jaundice
Symptoms: Abdominal pain, hepatomegaly
Clinical Findings: Abdominal pain, hepatomegaly, ultrasound discovers tumor of liver
Performance Scale (Karnofsky Score): ☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☐ 60-70 Symptomatic, in bed less than 50% of day ☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS				
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 5]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status
Not			

OB/GYN HISTORY			
Menopausal Status	Date of First Menses	# of Pregnancies	
☐ Pre-menopausal			
☐ Peri-Menopausal	Date of Last Menses	# of Live Births	
☐ Post-menopausal			
Birth Control: ☐ Condom ☐ Oral Contraceptive ☐ IUD ☐ Other: _____		☐ Hormone Replacement Therapy: _____	

SOCIAL HISTORY				
Occupation: _____		Environmental Hazards: Not		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☒ YES ☐ NO	Cigarette	1/9	(yrs)	(yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☒ YES ☐ NO	Alcohol	100 ml	(yrs)	(yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis
Not		

LAB DATA						
Test	Result	Date	Test	Result	Date	
HIV	☐ Negative ☐ Positive: _____		CEA	☐ Negative ☐ Positive: _____		
Hep B	☐ Negative ☐ Positive: _____		CA 15-3	☐ Negative ☐ Positive: _____		
Hep C	☐ Negative ☐ Positive: _____		CA 19-9	☐ Negative ☐ Positive: _____		
AFP	☐ Negative ☒ Positive: 1.46 ng/ml		PSA	☐ Negative ☐ Positive: _____		
Other:	☐ Negative ☐ Positive: _____		Other:	☐ Negative ☐ Positive: _____		
B/T Cell Markers:						

[page 3 of 5]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound	Live cancer	
X-Ray	Chest is normal	
CT	Live cancer	
Endoscopy		
MRI	Not	
Biopsy		

CLINICAL DIAGNOSIS		
Preoperative Clinical Diagnosis		
Tumor Resection		
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis	
Not	Not	
Clinical Staging		Date of Diagnosis
T ₃ N ₀ M ₀	Stage: III	

Treatment Information

SURGICAL TREATMENT			
Procedure		Date of Procedure	
Tumor Resection			
Primary Tumor			
Organ	Detailed Location	Size	
Liver		7.5 x 7 x 6 cm	
Extension of Tumor			
Not			
Lymph Nodes			
Description	Location of Lymph Nodes	# of Lymph Nodes	
Palpable, Non-Dissected Lymph Nodes	Not		
Dissected Lymph Nodes	Not		
Distant Metastasis			
Organ	Detailed Location	Size	
Not			
Surgical Staging			
T ₃ N ₀ M ₀		Stage: III	

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 5]
Microscopic Description

Histological Pattern											
Cell Distribution					Structural Pattern						
	+	-							+	-	
Diffuse		✓			Streaming						✓
Mosaic			✓		Storiform						✓
Necrosis		✓			Fibrosis						✓
Lymphocytic Infiltration			✓		Palisading						✓
Vascular Invasion			✓		Cystic Degeneration						✓
Clusterized			✓		Bleeding			✓			
Alveolar Formation			✓		Myxoid Change						✓
Indian File			✓		Psammoma/Calcification						✓

Cellular Differentiation											
Squamous			Adenomatous			Sarcomatous			Lymphomatous		
	+	-		+	-		+	-		+	-
Squamoid Cell		✓	Glandular cell	✓		Round Cell		✓	Large Cell		✓
Spindle Cell		✓	Cell Stratification	✓		Fibroblast		✓	Small Cell		✓
Keratin		✓	Secretion	✓		Osteoblast		✓	RS Cell/RS Like		✓
Desmosome		✓	Intracyt. Vacuole	✓		Lipoblast		✓	Inflam. Cell		✓
Pearl		✓	Gland formation	✓		Myoblast		✓	Plasma Cell		✓

Cellular Differentiation: Well ✓ Moderate Poor

Nuclear Appearance				
Nuclear Atypia:	0	I	II	III
Aniso Nucleosis		✓		
Hyperchromatism		✓		
Nucleolar Prominent		✓		
Multinucleated Giant Cell	✓			
Mitotic Activity		✓		
Nuclear Grade:		✓		

IHC Data			
Marker	Result	Value	Date
ER	☐ Negative ☐ Positive		
PR	☐ Negative ☐ Positive		
Her-2/neu	☐ Negative ☐ Positive		
B-Cell Marker	☐ Negative ☐ Positive		
T-Cell Marker	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		

Final Pathology Report

Histological Diagnosis: Well differentiated adenocarcinoma **Grade:** 1

Comments:

Principal Investigator

Pathologist

Date

[page 5 of 5]
Histological Pattern															
Cell Distribution			+	-	Structural Pattern				+	-					
Diffuse				/	Streaming										
Mosaic			/		Storiform										
Necrosis				/	Fibrosis										
Lymphocytic Infiltration			/		Palisading										
Vascular Invasion				/	Cystic Degeneration										
Clusterized			/		Bleeding										
Alveolar Formation				/	Myxoid Change										
Indian File				/	Psammoma/Calcification										
Cellular Differentiation															
Squamous		+	-	Adenomatous		+	-	Sarcomatous		+	-	Lymphomatous		+	-
Squamoid Cell				Glandular cell		/		Round Cell				Large Cell			
Spindle Cell				Cell Stratification		/		Fibroblast				Small Cell			
Keratin				Secretion		/		Osteoblast				RS Cell/RS Like			
Desmosome				Intracyt. Vacuole		/		Lipoblast				Inflam. Cell			
Pearl				Gland formation		/		Myoblast				Plasma Cell			
Cellular Differentiation: ☐ Well ☒ Moderate ☐ Poor															
Nuclear Appearance															
Nuclear Atypia:								0	I	II	III				
Aniso Nucleosis										/					
Hyperchromatism										/					
Nucleolar Prominent										/					
Multinucleated Giant Cell										/					
Mitotic Activity										/					
Nuclear Grade:										/					

Final Pathology Report

Histological Diagnosis: Hepatocellular carcinoma Grade: 2
Trabecular type

Comments:

Comments:

Director, Research Pathology

Date _____

INTEGRATED REPORT OF FINDINGS BY COLLABORATORS AND

PATHOLOGISTS -

	Yes	No
Critera		

Source: NCI Genomic Data Commons file 18ba2bed-d620-4122-9d56-ab7219cca652 (TCGA-CC-A9FV.01A31339-0FAD-4D49-ACD1-E357D32C887B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).